Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOC, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAOC-01A (Primary Tumor).

[page 1 of 4]
Operative Procedure: ORCHIECTOMY

- Specimen Source: L TESTICLE

- Gross Exam Date:

- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. TERATOMA, MATURE AND IMMATURE (6 X 6 X 6 CM), left radical orchiectomy. (see note)
2. TUMOR CONFINED TO TESTIS.
3. NO VASCULAR INVASION IDENTIFIED.
4. SURGICAL MARGINS FREE OF TUMOR.
5. NO RESIDUAL TESTICULAR PARENCHYMA IDENTIFIED

Note: A focus of possible yolk sac tumor is recognized. Special stains pending.

GROSS DESCRIPTION:

The specimen is received in one part, fixed in formalin, labeled with the patient's name, and "left testicle tumor." It consists of a previously bisected 170 gram orchiectomy specimen including 6 x 6 x 6 cm testis, 1 x 0.5 x 0.5 cm epididymis, 9 cm in length and 1.5 cm in diameter spermatic cord. On cross section, there is a 6 x 6 x 6 cm yellow-tan, well-circumscribed mass with multiple small cysts filled with mucinous material. The tumor appears to involve the whole testicular parenchyma. No normal testicular tissue identified. The spermatic cord consists of vas deferens, arteries and veins and is unremarkable.

Cassettes 1 and 2: Tumor and possible epididymis.

Cassette 3: Tumor and spermatic cord peritesticular portion.

Cassette 4: Midportion of spermatic cord.

Cassette 5: Spermatic cord resection margin.

ICD.O. 3

Teratoma (mature & immature) 908013

Site @ Testis NOS C62.9

9/13/14

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 4]
SURGICAL PATHOLOGY TISSUE REPORT

Name:

- Specimen Source: L TESTICLE
- Gross Exam Date:
- Physician:

Pager No.:

Cassettes 6 to 8: Additional sections from tumor.
R8.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

TABLE -

[page 3 of 4]
TISSUE REPORT

Name:

Sex:

Operative Procedure: ORCHIECTOMY

- Specimen Source: L TESTICLE

- Gross Exam Date:

- Physician:

Pager No.:

ADDENDUM to

The presence of multifocal yolk sac component is identified by AFP stain.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION																								

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Teratoma Mature and Immature	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Teratoma (Mature) 50%, Teratoma (Immature) 50%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file b73acde3-ddc3-484b-a7ba-49bd115d01d8 (TCGA-XE-AAOC.5D9A810C-4754-4F22-B6D4-82C5178B7C5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).